Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1E9, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1E9-01A (Primary Tumor).

[page 1 of 4]
ICB-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site code liver C22.0

1/19/11
hw

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Liver Segments II and III (380 grams, 18.3 x 10.8 x 4.8 cm).
A1, A2, A3, A4, A5, A6, A7, A8

DIAGNOSIS:

Liver, Segments II and III, partial hepatectomy: Grade 2 (of 4) hepatocellular carcinoma, usual type, forming a single 4.2 x 3.8 x 3.2 cm mass. The tumor is located in segments II and III. The hepatic capsule is involved, but adjacent organs spared. The surgical margins are free of tumor, the clearance being 2.5 cm. Extratumoral vascular invasion is not identified. The tumor is partially encapsulated, infiltration of parenchyma being of the pushing/infiltrating type. The non-neoplastic liver shows end-stage micronodular cirrhosis with steatosis and chronic inflammation. The tumor is classified as T2NX.

II/PAI Discrepancy		X

[page 2 of 4]
Patient Key:
Surgical date:

TISSUE DESCRIPTION:

Liver Segments II and III (380 grams, 18.3 x 10.8 x 4.8 cm).
A1, A2, A3, A4, A5, A6, A7, A8

DIAGNOSIS:

Liver, Segments II and III, partial hepatectomy: Grade 2 (of 4) hepatocellular carcinoma, usual type, forming a single 4.2 x 3.8 x 3.2 cm mass. The tumor is located in segments II and III. The hepatic capsule is involved, but adjacent organs spared. The surgical margins are free of tumor, the clearance being 2.5 cm. Extratumoral vascular invasion is not identified. The tumor is partially encapsulated, infiltration of parenchyma being of the pushing/infiltrating type. The non-neoplastic liver shows end-stage micronodular cirrhosis with steatosis and chronic inflammation. The tumor is classified as T2NX.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC**Specimen Type**

- ☐ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☒ Left lateral segmentectomy
☐ Total left lobectomy
☐ Explanted liver
☐ Other (specify): _____
☐ Not specified

Focality

- ☒ Solitary (specify location): Seg 2, 3
☐ Multiple (specify location): 6

Tumor Size

Greatest dimension 4.2 cm

*Additional dimensions: 2.8 x 4.0 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC**Histologic Type**

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☐ GI: Well differentiated
☒ GII: Moderately differentiated
☐ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☐ pT0: No evidence of primary tumor
☒ pT1: Solitary tumor with no vascular invasion
☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☐ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis
Specify: Number examined: ____
Number involved: ____

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☐ Cannot be assessed
☒ Uninvolved by invasive carcinoma 2.5, 0
Distance of invasive carcinoma from closest margin: ____ mm
Specify margin: _____

☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
☐ Uninvolved by invasive carcinoma
* ☐ Carcinoma in situ absent
* ☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

Specify margin: _____

- ☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☒ Absent
* ☐ Present
* ☐ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☒ Cirrhosis/fibrosis
* ☐ Iron overload
* ☒ Hepatitis (specify type): chronic inflammation
* ☒ Other (specify): steatosis

Source: NCI Genomic Data Commons file 6d16beca-f12a-4d27-bf44-0694a53701c1 (TCGA-DD-A1E9.07CF8AAC-8A8A-4E4C-BBDA-EDCD78608723.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).